Somatic mutation profile of tumor specimen TCGA-O8-A75V-01A (aliquot TCGA-O8-A75V-01A-11D-A32G-10) from TCGA case TCGA-O8-A75V, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.3 years (19,850 days).
Specimen TCGA-O8-A75V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edc95a2d-a6d4-4b0a-ac67-7bd0c8520c91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-O8-A75V-10A (Blood Derived Normal), aliquot TCGA-O8-A75V-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7617500-32b2-45f2-8853-d460fbad342d

The open-access MAF lists 95 somatic variants for this specimen: 64 protein-altering or splice-affecting, 31 silent.
By variant classification: Missense Mutation 48, Silent 31, Nonsense Mutation 7, Frame Shift Del 3, Splice Site 2, In Frame Del 1, Frame Shift Ins 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 47/155 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP3 | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57421505; called by muse, mutect2, varscan2
- ANKLE1 | c.1997A>T p.Q666L (on ENST00000394458; = p.Q612L on NM_152363.6) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66733166; called by muse, mutect2, varscan2
- ARHGEF18 | c.2046G>A p.K682= (on ENST00000359920 / NM_001130955.2; = p.K578= on NM_015318.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 22/77 reads (29%) | catalogued as COSV60474922; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2425C>G p.H809D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59479697, COSV59481258; called by muse, mutect2, varscan2
- AVIL | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57684122; called by muse, mutect2, varscan2
- BRMS1 | c.139+1G>T p.X47_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV60820890, COSV60821110; called by muse, varscan2
- CCDC96 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs781608378, COSV59509800; called by muse, mutect2, varscan2
- CEP89 | c.2189G>T p.R730L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV59863635, COSV59868308; called by muse, mutect2, varscan2
- CLTB | c.656T>C p.L219P (on ENST00000310418 / NM_007097.5; = p.L201P on NM_001834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51258062; called by muse, mutect2, varscan2
- COL6A3 | c.7102G>T p.G2368C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770166058, COSV55113724; called by muse, mutect2, varscan2
- DEK | c.202A>G p.M68V | Missense Mutation (SNP) | VAF 85/266 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs147997771; called by muse, mutect2, varscan2
- DNAH6 | c.1610T>G p.I537S | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV52886637; called by muse, mutect2, varscan2
- DSE | c.358A>T p.I120F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV59067887; called by muse, mutect2, varscan2
- FAM83H | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs781905219, COSV66354785; called by muse, mutect2, varscan2
- FGD6 | c.1171A>C p.N391H | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.135); catalogued as COSV59697692; called by muse, mutect2, varscan2
- FLG | c.9919C>A p.Q3307K | Missense Mutation (SNP) | VAF 94/160 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV64251230; called by muse, mutect2
- FLG | c.54T>A p.Y18* | Nonsense Mutation (SNP) | VAF 84/418 reads (20%) | catalogued as COSV64251234; called by muse, mutect2, varscan2
- GABRG2 | c.979G>A p.V327I (on ENST00000361925 / NM_001375343.1; = p.V287I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62723189; called by muse, mutect2, varscan2
- GAPVD1 | c.2262G>T p.R754S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.916); catalogued as COSV52928093; called by muse, mutect2, varscan2
- GPATCH8 | c.120+1G>T p.X40_splice | Splice Site (SNP) | VAF 26/98 reads (27%) | catalogued as COSV71283382, COSV71284735; called by muse, mutect2, varscan2
- IGF2R | c.4892A>G p.K1631R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.331); catalogued as COSV63633434; called by muse, mutect2, varscan2
- IGF2R | c.6850T>G p.F2284V | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV63633446; called by muse, mutect2, varscan2
- INSRR | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs759296297, COSV63873414; called by muse, mutect2, varscan2
- KLF15 | c.736G>T p.V246F | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV56181295; called by muse, mutect2, varscan2
- KNDC1 | c.3118G>T p.V1040L | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as rs368551158, COSV58847568; called by muse, mutect2, varscan2
- KRT79 | c.821A>C p.Q274P | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV57942632; called by muse, mutect2, varscan2
- KRTAP19-1 | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 22/110 reads (20%) | catalogued as COSV66861662; called by muse, mutect2, varscan2
- L3MBTL2 | c.777G>T p.W259C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53435278; called by muse, mutect2, varscan2
- MAP10 | c.2552A>G p.Y851C | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as COSV69365234; called by muse, mutect2, varscan2
- MFSD3 | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56743561; called by muse, mutect2, varscan2
- MTHFD2L | c.200T>C p.I67T (on ENST00000395759 / NM_001144978.2; = p.I9T on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV57471027; called by muse, mutect2, varscan2
- MUC16 | c.2901G>A p.W967* | Nonsense Mutation (SNP) | VAF 34/127 reads (27%) | catalogued as rs1359162780, COSV67499429; called by muse, mutect2, varscan2
- NADK2 | c.629A>G p.Y210C (on ENST00000381937 / NM_001085411.3; = p.Y47C on NM_153013.4) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs376035643; called by muse, mutect2, varscan2
- NAT10 | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV57666640; called by muse, mutect2, varscan2
- NCAM1 | c.1538C>T p.P513L (on ENST00000316851 / NM_181351.5; = p.P503L on NM_000615.7) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV57526145; called by muse, mutect2, varscan2
- NPB | c.378A>G p.*126Wext*41 | Nonstop Mutation (SNP) | VAF 49/165 reads (30%) | catalogued as COSV58712845; called by muse, mutect2, varscan2
- NUDCD3 | c.1030G>T p.G344C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58126906; called by muse, mutect2, varscan2
- PCARE | c.2581G>T p.E861* | Nonsense Mutation (SNP) | VAF 31/102 reads (30%) | catalogued as COSV59053684, COSV59058707; called by muse, mutect2, varscan2
- PCDHB13 | c.2098C>A p.L700I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53401722; called by muse, mutect2
- PCDHB16 | c.2153G>T p.R718M | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV53372422; called by muse, mutect2, varscan2
- PEG10 | c.412G>A p.E138K (on ENST00000482108 / NM_001040152.2; = p.E172K on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.184); catalogued as COSV71788739; called by muse, mutect2, varscan2
- POU4F1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65883783; called by muse, mutect2, varscan2
- PYGO2 | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV63757898; called by muse, mutect2, varscan2
- SLC12A4 | c.239C>G p.S80W | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57925852; called by muse, mutect2, varscan2
- SLCO1B3 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53947848; called by muse, mutect2, varscan2
- SMG1 | c.6605C>A p.S2202* | Nonsense Mutation (SNP) | VAF 81/172 reads (47%) | catalogued as COSV67175120, COSV67175146; called by muse, mutect2, varscan2
- ST14 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs749130417, COSV53837516; called by muse, mutect2, varscan2
- TAFA2 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV69189890; called by muse, mutect2, varscan2
- TBATA | c.70_72del p.K24del | In Frame Del (DEL) | VAF 10/65 reads (15%) | catalogued as rs756010080; called by pindel, varscan2
- TGM5 | c.410T>A p.I137N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV55012675; called by muse, mutect2, varscan2
- THBS4 | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs759429718, COSV63471230; called by muse, mutect2
- TMEM51 | c.91T>A p.W31R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65691536; called by muse, mutect2, varscan2
- TPO | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV61112621; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1353C>G p.N451K | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs147808288, COSV50553868; called by muse, mutect2, varscan2
- TRPM1 | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56643668; called by muse, mutect2, varscan2
- TTC13 | c.1741C>G p.P581A | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as COSV64170390; called by muse, mutect2, varscan2
- ZNF16 | c.263C>A p.S88* | Nonsense Mutation (SNP) | VAF 47/500 reads (9%) | catalogued as COSV52765999; called by muse, mutect2
- ZNF366 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs773161566, COSV59219566; called by muse, mutect2, varscan2
- FANCM | c.4364dup p.R1456Afs*13 | Frame Shift Ins (INS) | VAF 29/118 reads (25%) | called by mutect2, pindel, varscan2
- RTN1 | c.1307_1328del p.H436Rfs*12 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- TF | c.1740_1741del p.L580Ffs*4 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- TNXB | c.6397G>T p.E2133* (on ENST00000647633; = p.E1886* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- TRIP12 | c.3571del p.H1191Mfs*28 | Frame Shift Del (DEL) | VAF 38/183 reads (21%) | called by mutect2, pindel, varscan2
- ABCB1 | c.2364C>A p.L788= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV55965319; called by muse, mutect2, varscan2
- AKAP11 | c.3969A>T p.P1323= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as COSV50304299; called by muse, mutect2, varscan2
- ALS2CL | c.630A>G p.T210= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV59674050; called by muse, mutect2, varscan2
- AP1M1 | c.525C>A p.V175= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV52229507; called by muse, mutect2, varscan2
- CXCL2 | c.249A>G p.K83= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as rs746075939, COSV56022149; called by muse, mutect2, varscan2
- CYP7B1 | c.180G>T p.L60= | Silent (SNP) | VAF 146/196 reads (74%) | catalogued as COSV59598340; called by muse, mutect2, varscan2
- DHX8 | c.2631G>T p.T877= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV52253103, COSV52257060; called by muse, mutect2, varscan2
- DNAH10 | c.13383C>T p.P4461= (on ENST00000409039; = p.P4400= on NM_207437.3) | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs923769823, COSV53022625; called by muse, mutect2, varscan2
- ENOX2 | c.390A>G p.V130= (on ENST00000338144 / NM_001382520.1; = p.V101= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 64/117 reads (55%) | catalogued as COSV57658935; called by muse, mutect2, varscan2
- FANCD2 | c.249G>C p.L83= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as COSV55047753; called by muse, mutect2, varscan2
- FAT1 | c.8646T>C p.N2882= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs767714665, COSV71676252; called by muse, mutect2, varscan2
- HIF3A | c.999T>C p.S333= (on ENST00000377670 / NM_152795.4; = p.S264= on NM_022462.4) | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV52205616; called by muse, mutect2, varscan2
- HIVEP1 | c.2394A>T p.P798= | Silent (SNP) | VAF 71/201 reads (35%) | catalogued as COSV65105543; called by muse, mutect2, varscan2
- HLCS | c.1965G>T p.G655= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as COSV60797276; called by muse, mutect2, varscan2
- HMGCLL1 | c.534C>T p.S178= | Silent (SNP) | VAF 49/92 reads (53%) | catalogued as COSV51453150; called by muse, mutect2, varscan2
- IGSF9B | c.2688C>T p.N896= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs749283493, COSV58069721; called by muse, mutect2, varscan2
- LINGO3 | c.1671G>C p.G557= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV68261952; called by muse, mutect2, varscan2
- NLRX1 | c.2889C>A p.V963= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV52710493; called by muse, mutect2, varscan2
- RAD54L2 | c.3081G>A p.Q1027= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV56582039; called by muse, mutect2, varscan2
- SCRIB | c.3396G>A p.E1132= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV57594272; called by muse, mutect2, varscan2
- SLC8A3 | c.174C>T p.V58= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV63519839; called by muse, mutect2
- SORCS2 | c.2466C>T p.D822= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs373781482, COSV61184861; called by muse, mutect2, varscan2
- SRCIN1 | c.810T>G p.A270= (on ENST00000621492; = p.A236= on NM_025248.3) | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- TAS2R1 | c.24C>T p.I8= | Silent (SNP) | VAF 116/253 reads (46%) | catalogued as COSV101225865, COSV66779139; called by muse, mutect2, varscan2
- TMEM26 | c.234A>G p.P78= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV53264650; called by muse, mutect2, varscan2
- TNXB | c.1017G>A p.T339= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs762908509, COSV64490294; called by muse, mutect2, varscan2
- TRAK2 | c.1947A>G p.A649= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV60275690; called by muse, mutect2, varscan2
- TRMT61A | c.69T>A p.G23= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV54569916; called by muse, mutect2, varscan2
- TROAP | c.1213C>T p.L405= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as rs982259674, COSV57746258; called by muse, mutect2
- TTN | c.18264A>G p.E6088= (on ENST00000591111; = p.E5161= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/170 reads (30%) | catalogued as COSV60393441; called by muse, mutect2, varscan2
- ZNF467 | c.738C>T p.C246= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as COSV57374044; called by muse, mutect2, varscan2
